Somatic mutation profile of tumor specimen ALCH-B3CG-TTP1-A (aliquot ALCH-B3CG-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B3CG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.3 years (21,291 days).
Specimen ALCH-B3CG-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5afce8d-d7cf-4aaa-919b-bef1bb9c4faf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3CG-NB1-A (Blood Derived Normal), aliquot ALCH-B3CG-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/493a3d05-adfe-4466-aa77-781118ca3571

The open-access MAF lists 499 somatic variants for this specimen: 350 protein-altering or splice-affecting, 91 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 303, Silent 91, Intron 20, Nonsense Mutation 20, RNA 18, Splice Site 12, 3'UTR 9, Frame Shift Del 8, Splice Region 5, 5'UTR 5, 5'Flank 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GBA | c.1342G>C p.D448H | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs1064651, CM900106; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.2648T>C p.M883T | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761423259; called by muse, mutect2
- ABI3BP | c.2088G>T p.G696= | Splice Region (SNP) | VAF 24/137 reads (18%) | catalogued as COSV52547996; called by muse, mutect2, varscan2
- ABLIM3 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200588080; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2902G>A p.V968M | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1446307679, COSV65892613; called by muse, mutect2, varscan2
- AL592490.1 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1241982942; called by muse, mutect2, varscan2
- ANKRD36 | c.1858G>C p.A620P | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV70747316; called by muse, mutect2, varscan2
- ANO3 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs768170790; called by muse, mutect2
- APOBEC3G | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.786); catalogued as COSV101349111; called by muse, mutect2, varscan2
- ARHGAP31 | c.498C>A p.H166Q | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51797916; called by muse, mutect2, varscan2
- ASCL4 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60816266; called by mutect2, varscan2
- ATP1A2 | c.1085T>A p.V362E | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM080082; called by muse, mutect2
- BBOX1 | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV54190799, COSV54192226; called by muse, mutect2, varscan2
- BRINP1 | c.2005C>A p.L669M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV56302494, COSV56307679; called by muse, mutect2, varscan2
- C2CD3 | c.2074G>T p.G692C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388599958; called by muse, mutect2
- CALN1 | c.648C>A p.S216R (on ENST00000329008 / NM_001017440.3; = p.S258R on NM_031468.4) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100205160, COSV61122732; called by muse, mutect2, varscan2
- CCN4 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as rs764654100, COSV51533628; called by muse, mutect2, varscan2
- CDH18 | c.527C>G p.T176S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV56949667; called by muse, mutect2, varscan2
- CDKN2A | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 28/58 reads (48%) | catalogued as COSV58682729; called by muse, varscan2
- CFH | c.1799G>T p.G600V | Missense Mutation (SNP) | VAF 21/299 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV66412290; called by muse, mutect2
- CNOT4 | c.310C>A p.R104S | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100212364; called by muse, mutect2, varscan2
- COL1A2 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 154/630 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CM135141; called by muse, mutect2, varscan2
- COL23A1 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66792072; called by muse, mutect2
- CSMD3 | c.5285G>T p.C1762F (on ENST00000297405 / NM_001363185.1; = p.C1658F on NM_052900.3) | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52155954; called by muse, mutect2, varscan2
- CXCR2 | c.376A>T p.K126* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV100578737; called by muse, mutect2, varscan2
- DCC | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59081290; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs754135731; called by mutect2, varscan2*
- DNAH14 | c.8746G>A p.D2916N (on ENST00000445597; = p.D3719N on NM_001367479.1) | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1558493499, COSV59903542; called by muse, mutect2
- DOK5 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 223/367 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV99373858; called by muse, mutect2, varscan2
- DSG4 | c.1412T>C p.I471T | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs751284984; called by muse, mutect2, varscan2
- EGFLAM | c.632A>G p.N211S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.007); catalogued as rs746562810; called by muse, mutect2
- EPHA6 | c.2157G>T p.E719D (on ENST00000389672 / NM_001080448.3; = p.E111D on NM_173655.4) | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101060868; called by muse, mutect2, varscan2
- F13B | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759690063; called by muse, mutect2, varscan2
- FAM174C | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271637938, COSV58011960; called by muse, mutect2, varscan2
- FAM71B | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV57231734; called by muse, mutect2, varscan2
- FCGR2B | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs764919412; called by muse, mutect2, varscan2
- FGF14 | c.408A>T p.S136= | Splice Region (SNP) | VAF 37/332 reads (11%) | catalogued as COSV65957579; called by muse, mutect2, varscan2
- FSHR | c.1231A>G p.I411V | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV58623867; called by muse, mutect2, varscan2
- FUT9 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.221); catalogued as COSV100133852, COSV56157658; called by muse, mutect2, varscan2
- G6PC2 | c.40C>A p.H14N | Missense Mutation (SNP) | VAF 73/440 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs746671578; called by muse, mutect2, varscan2
- GATA3 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60516183; called by muse, mutect2, varscan2
- GLYATL2 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV99780344; called by muse, mutect2, varscan2
- GRIK2 | c.2668G>A p.V890I | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); catalogued as rs138146298; called by muse, mutect2, varscan2
- GRIN2B | c.1011-1G>T p.X337_splice | Splice Site (SNP) | VAF 54/314 reads (17%) | catalogued as COSV101662889; called by muse, mutect2, varscan2
- HENMT1 | c.1106C>G p.S369* | Nonsense Mutation (SNP) | VAF 23/149 reads (15%) | catalogued as rs748146308, COSV100898661; called by muse, mutect2, varscan2
- HES7 | c.431G>C p.R144P | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV58555182; called by muse, mutect2
- HRH4 | c.341T>A p.L114Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as COSV99907759; called by muse, varscan2
- IFNA5 | c.427G>C p.V143L | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.514); catalogued as COSV99423665; called by muse, mutect2, varscan2
- IKZF1 | c.1500G>T p.Q500H | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV100497902; called by muse, mutect2, varscan2
- IL17F | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60234029; called by muse, mutect2
- ILDR2 | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV54828128; called by muse, mutect2, varscan2
- IRF7 | c.844C>T p.P282S (on ENST00000397566; = p.P269S on NM_001572.5) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as rs1480503506, COSV52752162; called by muse, mutect2, varscan2
- ITGA8 | c.2443G>T p.E815* | Nonsense Mutation (SNP) | VAF 27/254 reads (11%) | catalogued as COSV65230378, COSV65237607; called by muse, mutect2, varscan2
- KCNA5 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as COSV52904843; called by muse, mutect2, varscan2
- KIR3DL3 | c.1111T>A p.S371T | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.953); catalogued as COSV52547100; called by muse, mutect2, varscan2
- KLHL18 | c.1447G>T p.G483W | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51746041; called by muse, mutect2
- KLHL35 | c.1057T>C p.Y353H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs745420682; called by muse, mutect2, varscan2
- KMT5C | c.734G>T p.R245M | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV99726314; called by muse, mutect2, varscan2
- LBR | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs927660579; called by muse, mutect2, varscan2
- LPO | c.2101A>T p.K701* | Nonsense Mutation (SNP) | VAF 19/120 reads (16%) | catalogued as COSV51856648; called by muse, mutect2, varscan2
- LRP2 | c.10946C>A p.P3649Q | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55561642, COSV55575292, COSV55579497; called by muse, mutect2, varscan2
- MAGEA6 | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61448782; called by muse, mutect2, varscan2
- MAGEC1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV53578117, COSV53578198; called by muse, mutect2, varscan2
- MDGA2 | c.2684A>T p.N895I (on ENST00000399232 / NM_001113498.2; = p.N597I on NM_182830.4) | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV62081066; called by muse, mutect2
- MKI67 | c.6677C>T p.P2226L | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs199745998; called by muse, mutect2, varscan2
- MORC1 | c.1802del p.G601Afs*4 | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | catalogued as COSV51713439; called by mutect2, pindel
- MUC12 | c.1039G>A p.D347N (on ENST00000379442; = p.D204N on NM_001164462.1) | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs778509336; called by muse, mutect2
- MYH1 | c.4441C>T p.L1481F | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs185795474; called by muse, mutect2, varscan2
- NAA35 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.147); catalogued as COSV100863446; called by muse, mutect2, varscan2
- NALCN | c.2342C>A p.S781Y | Missense Mutation (SNP) | VAF 40/359 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV51916871; called by muse, mutect2, varscan2
- NALCN | c.1441C>G p.R481G | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51945531; called by muse, mutect2, varscan2
- NID2 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV53493165, COSV53494990; called by muse, varscan2
- NKX2-4 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 23/259 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61085975; called by muse, mutect2
- NPR2 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs774161439, COSV100709564, COSV61309849; called by muse, mutect2
- NT5C1B | c.413C>G p.P138R (on ENST00000359846 / NM_001199086.2; = p.P78R on NM_033253.4) | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as rs200286986; called by muse, mutect2, varscan2
- OPCML | c.829C>A p.R277S | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV59455705; called by muse, mutect2, varscan2
- OR10H4 | c.8G>T p.S3I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV59061751; called by muse, mutect2, varscan2
- OR14K1 | c.383T>A p.L128Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1444800853; called by muse, mutect2
- OR2G3 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV100180506; called by muse, mutect2
- OR4N2 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60054949; called by muse, mutect2
- OR4N2 | c.851C>G p.P284R | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60051256; called by muse, mutect2
- OR51A2 | c.878A>G p.Y293C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs200401320; called by muse, varscan2
- PABPC4L | c.874G>T p.G292W | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV69929687; called by muse, mutect2, varscan2
- PARD3 | c.3829G>T p.A1277S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs202148989; called by muse, mutect2, varscan2
- PCDHB7 | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.088); catalogued as rs782535815, COSV50762150, COSV50823479; called by muse, mutect2, varscan2
- PCDHGB6 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as COSV53992828; called by muse, mutect2
- PLGRKT | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 129/284 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs983625383, COSV99804067; called by muse, mutect2, varscan2
- PNPLA6 | c.2308C>T p.P770S (on ENST00000414982 / NM_001166111.2; = p.P722S on NM_006702.5) | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as rs748337187; called by muse, mutect2
- PRR23A | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.79); catalogued as COSV67214561; called by muse, mutect2, varscan2
- PTEN | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV64292670; called by muse, mutect2
- REG3G | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55449435; called by muse, mutect2, varscan2
- RFPL4A | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 38/522 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs1451258082; called by muse, mutect2
- RGS7 | c.670del p.H224Tfs*39 | Frame Shift Del (DEL) | VAF 37/279 reads (13%) | catalogued as COSV58555339; called by mutect2, pindel, varscan2
- RNF148 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57381057; called by muse, mutect2, varscan2
- RO60 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 22/231 reads (10%) | catalogued as COSV66473809; called by muse, mutect2
- ROS1 | c.7021G>A p.G2341R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); catalogued as rs1442866318; called by muse, mutect2, varscan2
- RXFP2 | c.530C>A p.S177Y | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53642183; called by muse, mutect2
- SCN1A | c.4761G>C p.E1587D (on ENST00000303395 / NM_001202435.3; = p.E1576D on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57688639; called by muse, mutect2, varscan2
- SCN2A | c.2659G>T p.V887L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV51832990, COSV51850415; called by muse, mutect2, varscan2
- SIK3 | c.389G>A p.R130Q (on ENST00000445177 / NM_001366686.2; = p.R136Q on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs751793973; called by muse, mutect2
- SLC27A6 | c.794T>A p.L265Q | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758325246; called by muse, mutect2, varscan2
- SPI1 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.275); catalogued as COSV57028655; called by muse, mutect2, varscan2
- SPIN4 | c.421del p.V141Sfs*7 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as COSV100633360; called by mutect2, pindel
- SULT1B1 | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs772474546; called by muse, mutect2, varscan2
- SYNRG | c.2182G>A p.V728M | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs766394151; called by muse, mutect2, varscan2
- TAS2R39 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 58/307 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV71470907; called by muse, mutect2, varscan2
- TBX15 | c.1019A>T p.Q340L (on ENST00000369429 / NM_001330677.2; = p.Q234L on NM_152380.3) | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV52869650; called by muse, mutect2, varscan2
- TEX55 | c.984T>A p.S328R | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.719); catalogued as rs774204173; called by muse, mutect2, varscan2
- TFAP2D | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV104375655, COSV50422785; called by muse, mutect2, varscan2
- TFR2 | c.2343G>C p.W781C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM136283; called by muse, varscan2
- TGFBRAP1 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99305492; called by muse, mutect2, varscan2
- TMPRSS15 | c.2893G>C p.D965H | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53035131, COSV53035233, COSV53044588; called by muse, mutect2, varscan2
- TNS1 | c.4687G>T p.A1563S | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1254327892; called by muse, mutect2, varscan2
- TP53 | c.208del p.A70Lfs*53 | Frame Shift Del (DEL) | VAF 8/98 reads (8%) | catalogued as COSV53716244; called by mutect2, pindel
- TRPM1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as rs530420639; called by mutect2, varscan2
- TTN | c.24778C>G p.P8260A (on ENST00000591111; = p.P7333A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/165 reads (13%) | PolyPhen benign (0.006); catalogued as COSV59906672; called by muse, mutect2, varscan2
- TULP1 | c.72C>A p.S24R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV57694071; called by muse, mutect2, varscan2
- UBA3 | c.746G>A p.C249Y | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62741336; called by muse, mutect2, varscan2
- USH2A | c.8671G>T p.G2891C | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1316891540; called by muse, mutect2
- WDR64 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as COSV63795522, COSV63798791; called by muse, mutect2, varscan2
- WNT5A | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1467578208; called by muse, mutect2, varscan2
- ZNF160 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61998988; called by muse, mutect2
- ZNF71 | c.993C>G p.C331W | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60149051; called by muse, mutect2, varscan2
- ZNF804B | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1385801837; called by muse, mutect2, varscan2
- ZYG11A | c.1909C>A p.R637S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV101033275; called by muse, mutect2, varscan2
- ABCA10 | c.3268A>G p.M1090V | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCA8 | c.3100G>T p.V1034F | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ABCD3 | c.1873C>A p.H625N | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ACSM3 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- ACTBL2 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACTN4 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.011); called by mutect2, varscan2
- ADAMTS16 | c.2246G>T p.R749M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2
- ADAMTSL3 | c.2819A>T p.Q940L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADD2 | c.1132A>T p.R378* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | called by muse, varscan2
- ADGB | c.2609T>A p.V870D | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- ADGRV1 | c.8870G>T p.G2957V | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADIPOQ | c.459C>A p.N153K | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.376); called by muse, mutect2
- AGBL4 | c.456T>A p.F152L | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- AHNAK | c.2170G>T p.G724* | Nonsense Mutation (SNP) | VAF 23/193 reads (12%) | called by muse, mutect2, varscan2
- ALCAM | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ALPK1 | c.3139A>G p.R1047G | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANKRD36 | c.971C>T p.T324I | Missense Mutation (SNP) | VAF 14/383 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- ANKRD60 | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ANKUB1 | c.1159A>T p.S387C | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ANO4 | c.2583C>A p.Y861* (on ENST00000392977 / NM_001286615.2; = p.Y826* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 23/166 reads (14%) | called by muse, mutect2, varscan2
- ANO5 | c.995T>C p.M332T | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ARHGAP30 | c.1086C>A p.N362K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP44 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- ARMCX5-GPRASP2 | c.635del p.K212Rfs*6 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel
- ATP13A4 | c.604-2A>C p.X202_splice | Splice Site (SNP) | VAF 26/267 reads (10%) | called by muse, mutect2
- ATP4A | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATP7A | c.634A>T p.T212S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AUP1 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- BEND6 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- BFSP2 | c.622T>A p.S208T | Missense Mutation (SNP) | VAF 44/483 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- BHLHA9 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.181); called by muse, mutect2
- BRDT | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRSK2 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- C10orf67 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 23/270 reads (9%) | called by muse, mutect2
- C2CD3 | c.2075G>C p.G692A | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CADM1 | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CADPS | c.3027G>T p.K1009N | Missense Mutation (SNP) | VAF 8/215 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- CALD1 | c.2335T>C p.W779R (on ENST00000361675 / NM_033138.4; = p.W524R on NM_004342.7) | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAP2 | c.-1-1G>T | Splice Site (SNP) | VAF 12/72 reads (17%) | called by muse, varscan2
- CASQ1 | c.827G>T p.W276L | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CDC14C | c.394C>G p.R132G (on ENST00000428251; = p.R25G on NM_152627.3) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CEP70 | c.968A>C p.K323T | Missense Mutation (SNP) | VAF 89/544 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP54 | c.4203G>A p.M1401I | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- CFHR1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 41/339 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CHAT | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CHN1 | c.568A>T p.R190* | Nonsense Mutation (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- CHP2 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CLPTM1L | c.1310T>G p.V437G | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CNTNAP2 | c.3337C>A p.H1113N | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- COL21A1 | c.1466T>A p.V489D | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- COL25A1 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- COL4A3 | c.2264C>A p.P755Q | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by muse, mutect2
- COL6A5 | c.6409A>C p.I2137L (on ENST00000312481; = p.I2133L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/335 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.545); called by muse, mutect2
- CPED1 | c.2555G>A p.G852D | Missense Mutation (SNP) | VAF 13/253 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CR1 | c.4642T>C p.C1548R | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CYP4F3 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); called by muse, mutect2
- DAAM2 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- DACH1 | c.1511C>A p.P504H (on ENST00000619232 / NM_001366712.1; = p.P452H on NM_080759.6) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- DBF4 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX3X | c.447_448del p.S151Wfs*7 (on ENST00000399959; = p.S152Wfs*7 on NM_001356.5) | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by pindel, varscan2
- DDX50 | c.1880A>G p.K627R | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2
- DEFB119 | c.60A>G p.S20= | Splice Region (SNP) | VAF 35/166 reads (21%) | called by muse, mutect2, varscan2
- DGAT2 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DGKI | c.994-1G>C p.X332_splice | Splice Site (SNP) | VAF 25/192 reads (13%) | called by muse, mutect2, varscan2
- DNAH5 | c.7713G>T p.R2571S | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DNAI1 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 245/549 reads (45%) | called by muse, mutect2, varscan2
- DPPA5 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- DSCAML1 | c.742C>A p.Q248K (on ENST00000321322; = p.Q188K on NM_020693.4) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); called by muse, mutect2
- DZIP1 | c.685+1G>T p.X229_splice | Splice Site (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- ECEL1 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- EIF4G1 | c.829G>C p.E277Q (on ENST00000346169 / NM_198241.3; = p.E81Q on NM_004953.5) | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENOSF1 | c.736G>C p.G246R (on ENST00000340116 / NM_001354066.2; = p.G198R on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENPP3 | c.1201G>C p.G401R | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERI2 | c.23+3A>T | Splice Region (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- EYS | c.6450C>G p.F2150L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- EYS | c.3037T>G p.C1013G | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- FFAR4 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.096); called by muse, mutect2
- FGD5 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- FLG | c.3025C>A p.H1009N | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.066); called by muse, varscan2
- FN1 | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FPR2 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2
- GALNTL6 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIMAP8 | c.1919T>A p.V640D | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- GLRX3 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNAS | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by mutect2, varscan2
- GRID1 | c.2167T>A p.S723T | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.149); called by muse, mutect2
- GRM1 | c.1426C>A p.P476T | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM8 | c.1682G>C p.R561T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2
- HAL | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2
- HCN1 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- HDAC4 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HEATR4 | c.2959A>G p.R987G | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.205); called by muse, varscan2
- HECTD4 | c.2895G>T p.K965N | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HES7 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- HIP1 | c.1446C>G p.H482Q | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HTATSF1 | c.1702A>T p.N568Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- IFI27L1 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV1-16 | c.197C>G p.P66R | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- IGKV4-1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- INTS1 | c.1233G>T p.K411N | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- KBTBD12 | c.1070G>T p.R357M | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.292); called by muse, mutect2
- KCNA4 | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNJ5 | c.998T>C p.F333S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KCNU1 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.91); called by muse, mutect2
- KIF2B | c.217del p.L73Wfs*7 | Frame Shift Del (DEL) | VAF 17/123 reads (14%) | called by mutect2, pindel, varscan2
- LANCL1 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LILRA2 | c.1217T>A p.L406Q | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LMOD2 | c.557C>A p.S186Y | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); called by muse, varscan2
- LRRN1 | c.190A>T p.T64S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MARCHF2 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBOAT4 | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- MDGA2 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- MECOM | c.2283C>T p.Y761= (on ENST00000468789 / NM_001105078.4; = p.Y949= on NM_004991.4) | Splice Region (SNP) | VAF 46/307 reads (15%) | called by muse, mutect2, varscan2
- MMGT1 | c.237-2A>G p.X79_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- MPP3 | c.524-1G>T p.X175_splice | Splice Site (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- MTRR | c.1930G>C p.E644Q (on ENST00000264668; = p.E617Q on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.116); called by muse, mutect2
- MX2 | c.1650+1G>T p.X550_splice | Splice Site (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- MYOM2 | c.4327C>A p.P1443T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAV3 | c.3533T>C p.L1178P | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NDUFAF1 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); called by muse, mutect2
- NELFA | c.968C>T p.S323F (on ENST00000542778; = p.S312F on NM_005663.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, varscan2
- NES | c.253G>C p.A85P | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- NRL | c.217T>A p.Y73N | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- NUTM2D | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NYAP2 | c.1481C>A p.T494N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ODF2 | c.1265A>T p.Q422L (on ENST00000434106 / NM_153433.2; = p.Q398L on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.068); called by muse, mutect2
- OR10K2 | c.752A>T p.H251L | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR14K1 | c.385C>A p.H129N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2
- OR2F2 | c.220G>C p.A74P | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4D9 | c.624G>C p.W208C | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.22); called by muse, mutect2
- OR51A2 | c.802C>A p.H268N | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.029); called by muse, varscan2
- OR51B6 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5H1 | c.124A>T p.N42Y | Missense Mutation (SNP) | VAF 24/341 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5K4 | c.45A>G p.I15M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, varscan2
- OR5K4 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- OR6C74 | c.794G>C p.R265T | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); called by muse, mutect2
- OR6K3 | c.755C>G p.A252G (on ENST00000368146; = p.A236G on NM_001005327.2) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR6Y1 | c.668A>T p.Y223F | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR7C1 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by mutect2, varscan2
- OTOGL | c.5189G>C p.R1730T (on ENST00000547103; = p.R1721T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- PCDH11Y | c.2086G>T p.V696F (on ENST00000400457 / NM_032973.2; = p.V685F on NM_032971.3) | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PCDHB2 | c.1076C>G p.P359R | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); called by muse, mutect2
- PCDHGA8 | c.1040T>C p.V347A | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); called by muse, mutect2
- PCNT | c.2872G>T p.G958C | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- PDE3A | c.2017G>T p.A673S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PGM2L1 | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 33/409 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- PKD1L1 | c.4490G>T p.G1497V | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PKM | c.378+1G>T p.X126_splice | Splice Site (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- PLCB2 | c.2906C>A p.P969Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.023); called by muse, mutect2
- PLEC | c.12208A>T p.S4070C (on ENST00000322810 / NM_201380.4; = p.S3960C on NM_000445.5) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PLEC | c.4340_4353del p.E1447Gfs*38 (on ENST00000322810 / NM_201380.4; = p.E1337Gfs*38 on NM_000445.5) | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel
- PPP1R16B | c.764T>C p.V255A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PRAG1 | c.3826C>T p.Q1276* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- RAB3C | c.371+1G>C p.X124_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2
- RAB3GAP2 | c.2609A>T p.E870V | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.415); called by muse, mutect2
- RALGAPA2 | c.3026A>C p.K1009T | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- RALGPS1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- REG3G | c.133A>T p.K45* | Nonsense Mutation (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
- RFX2 | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- RNF20 | c.1295A>T p.K432M | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ROS1 | c.7022G>T p.G2341V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RP1 | c.522G>T p.R174S | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2
- RYR2 | c.7777G>T p.V2593L | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SAE1 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- SAXO2 | c.826A>T p.N276Y | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SCART1 | c.2120G>C p.W707S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by mutect2, varscan2
- SCMH1 | c.1930C>T p.P644S (on ENST00000326197 / NM_001031694.2; = p.P575S on NM_012236.4) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SCN2A | c.4705G>T p.V1569L | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.261); called by muse, mutect2
- SETD4 | c.1116G>C p.E372D | Missense Mutation (SNP) | VAF 11/275 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SF3B2 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); called by muse, mutect2
- SLC15A4 | c.268C>G p.P90A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- SLCO5A1 | c.354G>T p.R118S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SNRNP200 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SPACA1 | c.810A>T p.K270N | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- SPATA9 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); called by muse, mutect2
- SPTY2D1 | c.729C>G p.S243R | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- ST6GAL2 | c.1103T>C p.V368A | Missense Mutation (SNP) | VAF 28/116 reads (24%) | PolyPhen benign (0.422); called by muse, mutect2, varscan2
- STAB2 | c.2815G>T p.E939* | Nonsense Mutation (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2, varscan2
- STXBP5L | c.754-2A>C p.X252_splice | Splice Site (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- TBX3 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TDRD15 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEDC1 | c.1133G>T p.R378L (on ENST00000392523 / NM_001367178.1; = p.R309L on NM_001134875.1) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TF | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- THSD7A | c.4745C>A p.P1582H | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM132E | c.635C>A p.P212H (on ENST00000321639; = p.P302H on NM_001304438.2) | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNR | c.3484C>A p.Q1162K | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TRIB3 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- TRIM58 | c.832T>C p.C278R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, varscan2
- TRPM7 | c.2989-2A>T p.X997_splice | Splice Site (SNP) | VAF 8/54 reads (15%) | called by muse, varscan2
- TRPV4 | c.2453G>T p.R818L | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- TSPY1 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 14/466 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.154); called by muse, mutect2
- TSPYL6 | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.069); called by muse, varscan2
- TSPYL6 | c.797T>A p.I266N | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- TTN | c.21187C>G p.L7063V (on ENST00000591111; = p.L6136V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/209 reads (12%) | PolyPhen benign (0.113); called by muse, mutect2, varscan2
- TULP1 | c.71G>A p.S24N | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- UBE2S | c.34A>G p.I12V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBE4B | c.1964A>G p.E655G (on ENST00000343090 / NM_001105562.3; = p.E526G on NM_006048.5) | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- UCP1 | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UFL1 | c.2117G>T p.G706V | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC5D | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- USH2A | c.5810G>T p.G1937V | Missense Mutation (SNP) | VAF 59/414 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- USP17L7 | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP8 | c.2091A>T p.K697N | Missense Mutation (SNP) | VAF 35/337 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- VGLL2 | c.748C>A p.R250S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- WAPL | c.1238T>A p.F413Y | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- WDR27 | c.1640G>T p.C547F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WDR64 | c.915G>T p.L305F | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- WWC3 | c.2094G>C p.Q698H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- WWC3 | c.2095G>T p.E699* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- XIRP2 | c.1893T>A p.S631R (on ENST00000628543; = p.S806R on NM_152381.6) | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZAN | c.3302A>G p.Y1101C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ZBED6 | c.2587G>T p.A863S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ZDHHC16 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- ZFHX4 | c.5423C>A p.P1808H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ZFPM2 | c.1179A>T p.R393S | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ZNF208 | c.2683G>T p.G895C | Missense Mutation (SNP) | VAF 45/395 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF366 | c.2122A>C p.T708P | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF493 | c.1837T>A p.Y613N | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ZNF560 | c.1048T>A p.C350S | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ZNF561 | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF628 | c.2474C>T p.P825L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF675 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ZNF836 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ZNF91 | c.607G>T p.V203F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ACTN4 | c.855G>A p.L285= | Silent (SNP) | VAF 29/234 reads (12%) | called by muse, mutect2, varscan2
- ADCY1 | c.2467C>A p.R823= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV52035527; called by muse, mutect2, varscan2
- ADGRB3 | c.396A>T p.R132= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as COSV65404896; called by muse, mutect2, varscan2
- APOB | c.11331A>C p.S3777= | Silent (SNP) | VAF 22/384 reads (6%) | called by muse, mutect2
- APOBEC3B | c.81C>G p.L27= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP40 | c.1164C>T p.L388= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV54805145; called by muse, mutect2, varscan2
- ASNSD1 | c.1656C>T p.F552= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs1203254311; called by muse, varscan2
- BICD2 | c.1173A>T p.T391= | Silent (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- CDH6 | c.2031G>A p.L677= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- CDK4 | c.24A>T p.P8= | Silent (SNP) | VAF 24/242 reads (10%) | called by muse, mutect2
- CELA2A | c.54G>A p.G18= | Silent (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- CENPK | c.519G>A p.K173= | Silent (SNP) | VAF 30/194 reads (15%) | called by muse, mutect2, varscan2
- CER1 | c.96C>A p.P32= | Silent (SNP) | VAF 53/152 reads (35%) | called by muse, mutect2, varscan2
- CFAP100 | c.66C>A p.S22= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV61503062; called by muse, mutect2
- CFAP46 | c.951G>A p.K317= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as rs144339867; called by muse, mutect2
- CFAP61 | c.2559C>G p.L853= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2742C>A p.T914= | Silent (SNP) | VAF 43/177 reads (24%) | catalogued as COSV62195474; called by muse, mutect2, varscan2
- CNTNAP5 | c.24C>A p.T8= | Silent (SNP) | VAF 47/215 reads (22%) | called by muse, mutect2, varscan2
- COL6A5 | c.3300T>A p.G1100= | Silent (SNP) | VAF 24/188 reads (13%) | called by muse, mutect2, varscan2
- COPG1 | c.1974C>T p.H658= | Silent (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- CTNNA2 | c.969G>C p.T323= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV63556450; called by muse, mutect2, varscan2
- DNAH6 | c.2826A>T p.V942= | Silent (SNP) | VAF 11/203 reads (5%) | called by muse, mutect2
- DST | c.21531A>T p.V7177= (on ENST00000361203 / NM_001374722.1; = p.V4874= on NM_015548.5) | Silent (SNP) | VAF 22/337 reads (7%) | called by muse, mutect2
- EPHA3 | c.1485C>A p.T495= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV60708362; called by muse, mutect2, varscan2
- ESRRG | c.180C>A p.G60= | Silent (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- FAM135B | c.1533A>T p.A511= | Silent (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- FCAR | c.45G>T p.L15= | Silent (SNP) | VAF 15/156 reads (10%) | called by muse, mutect2, varscan2
- FCRL3 | c.2073C>T p.L691= | Silent (SNP) | VAF 24/143 reads (17%) | catalogued as COSV63839060; called by muse, mutect2, varscan2
- FLRT1 | c.91C>T p.L31= | Silent (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- FNBP1 | c.54A>G p.T18= | Silent (SNP) | VAF 37/344 reads (11%) | called by muse, mutect2, varscan2
- GABRA3 | c.1362G>A p.K454= | Silent (SNP) | VAF 35/144 reads (24%) | called by muse, mutect2, varscan2
- GCK | c.1116G>A p.E372= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs775856595; called by muse, mutect2, varscan2
- GPD2 | c.1434A>T p.T478= | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- GRAMD2B | c.1173A>T p.A391= | Silent (SNP) | VAF 24/195 reads (12%) | catalogued as rs1280443962; called by muse, mutect2, varscan2
- HAL | c.1659G>A p.L553= | Silent (SNP) | VAF 21/286 reads (7%) | called by muse, mutect2
- HP1BP3 | c.1161C>T p.T387= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV56563886; called by muse, mutect2, varscan2
- ICOS | c.399A>T p.S133= | Silent (SNP) | VAF 37/284 reads (13%) | called by muse, mutect2, varscan2
- IGF1R | c.3663C>A p.V1221= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV99163319; called by muse, mutect2, varscan2
- IL2 | c.390G>A p.E130= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as rs1210225942; called by muse, mutect2, varscan2
- INPP5F | c.603C>T p.L201= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs951620481; called by muse, mutect2, varscan2
- ITIH6 | c.2088C>A p.T696= | Silent (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- KCNA5 | c.678C>A p.P226= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs750529130, COSV52904586; called by muse, mutect2, varscan2
- KRI1 | c.1227G>A p.V409= | Silent (SNP) | VAF 19/145 reads (13%) | called by muse, mutect2, varscan2
- LOXL3 | c.1029G>C p.V343= | Silent (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- MC2R | c.504C>T p.F168= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- MROH6 | c.252C>T p.S84= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- MYCBPAP | c.1995C>A p.L665= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- MYCN | c.867C>T p.S289= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV55259158; called by muse, mutect2, varscan2
- MYO7A | c.657C>A p.I219= | Silent (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- NCAM2 | c.459G>A p.E153= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs1406622061; called by muse, mutect2, varscan2
- OR14I1 | c.597C>A p.A199= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- OR4K5 | c.621C>A p.S207= | Silent (SNP) | VAF 28/261 reads (11%) | called by muse, mutect2, varscan2
- OR51F2 | c.570C>A p.S190= | Silent (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2
- OR5T3 | c.427C>T p.L143= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as COSV100282882; called by muse, mutect2, varscan2
- OR6C76 | c.183C>A p.L61= | Silent (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- OTX2 | c.528C>A p.P176= (on ENST00000408990 / NM_172337.3; = p.P184= on NM_021728.4) | Silent (SNP) | VAF 13/167 reads (8%) | catalogued as rs766762080; called by muse, mutect2
- PCDH11Y | c.2085G>T p.V695= (on ENST00000400457 / NM_032973.2; = p.V684= on NM_032971.3) | Silent (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- PCDH11Y | c.2958T>A p.T986= (on ENST00000400457 / NM_032973.2; = p.T975= on NM_032971.3) | Silent (SNP) | VAF 28/163 reads (17%) | called by muse, mutect2, varscan2
- PITPNM3 | c.1342C>T p.L448= | Silent (SNP) | VAF 27/149 reads (18%) | called by muse, mutect2, varscan2
- PKN1 | c.1408C>T p.L470= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- PRR14L | c.6033A>G p.S2011= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV57884814; called by muse, mutect2, varscan2
- RASGRP3 | c.1449C>T p.S483= (on ENST00000402538 / NM_001349975.2; = p.S482= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 13/175 reads (7%) | called by muse, mutect2
- ROBO1 | c.2907A>G p.E969= | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- RPTOR | c.1290C>A p.P430= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2
- SAE1 | c.21T>A p.A7= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, varscan2
- SATB2 | c.1428G>A p.V476= | Silent (SNP) | VAF 36/220 reads (16%) | catalogued as rs753471227; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDS | c.69C>A p.A23= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV57452915; called by muse, mutect2, varscan2
- SEC23B | c.1368A>G p.T456= | Silent (SNP) | VAF 15/367 reads (4%) | called by muse, mutect2
- SI | c.4923A>G p.E1641= | Silent (SNP) | VAF 33/466 reads (7%) | called by muse, mutect2
- SI | c.2199G>A p.E733= | Silent (SNP) | VAF 76/647 reads (12%) | called by muse, mutect2, varscan2
- SLC7A9 | c.927G>C p.V309= | Silent (SNP) | VAF 23/152 reads (15%) | called by muse, mutect2, varscan2
- SON | c.2985T>C p.S995= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs1022320616; called by muse, mutect2, varscan2
- SOX6 | c.912C>G p.P304= | Silent (SNP) | VAF 22/302 reads (7%) | catalogued as rs772358464, COSV100323421, COSV57035743; called by muse, mutect2
- SRPRA | c.1722T>C p.S574= | Silent (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- STK32B | c.660G>T p.R220= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1341825382; called by muse, mutect2, varscan2
- STK36 | c.3192G>T p.S1064= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as COSV55325489; called by muse, mutect2, varscan2
- SUN2 | c.486G>A p.A162= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs758870911, COSV99325736; called by mutect2, varscan2
- SYNE1 | c.20628G>C p.T6876= (on ENST00000367255 / NM_182961.4; = p.T6805= on NM_033071.3) | Silent (SNP) | VAF 28/172 reads (16%) | called by muse, mutect2, varscan2
- TDRD6 | c.5613G>A p.P1871= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs1322938145; called by muse, mutect2, varscan2
- TLR4 | c.369T>A p.S123= (on ENST00000355622 / NM_138554.5; = p.S83= on NM_003266.4) | Silent (SNP) | VAF 10/60 reads (17%) | called by muse, varscan2
- TMCO6 | c.195C>A p.T65= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs558148339; called by muse, mutect2, varscan2
- TNS1 | c.4686G>A p.L1562= | Silent (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- TPRN | c.12G>A p.L4= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs915783513; called by mutect2, varscan2
- TPTE | c.192C>G p.S64= (on ENST00000618007 / NM_199261.4; = p.S46= on NM_199259.4) | Silent (SNP) | VAF 17/607 reads (3%) | catalogued as rs1454653281; called by muse, mutect2
- TRIM15 | c.855G>A p.L285= | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- TXNDC9 | c.645A>T p.R215= | Silent (SNP) | VAF 53/195 reads (27%) | called by muse, mutect2, varscan2
- USP29 | c.1959C>T p.D653= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV54141222; called by muse, mutect2, varscan2
- WDR59 | c.93A>T p.A31= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as rs376539535; called by muse, mutect2, varscan2
- ZIC1 | c.744C>A p.T248= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV51553235; called by muse, mutect2, varscan2
- ZMYND8 | c.900C>T p.D300= (on ENST00000311275 / NM_001363741.2; = p.D320= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as rs188899473; called by muse, mutect2, varscan2
- ZNF236 | c.4482C>T p.T1494= | Silent (SNP) | VAF 7/152 reads (5%) | called by muse, mutect2
- AC073343.1 | n.214A>G | RNA (SNP) | VAF 16/192 reads (8%) | catalogued as rs1177087260; called by muse, mutect2
- AC103993.1 | n.192G>T | RNA (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- ACAD9 | c.150+132A>G | Intron (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- AL450442.1 | n.818C>A | RNA (SNP) | VAF 21/156 reads (13%) | called by muse, mutect2, varscan2
- AP5Z1 | c.-17C>T | 5'UTR (SNP) | VAF 14/70 reads (20%) | catalogued as rs1161831311; called by muse, varscan2
- C8orf87 | n.54C>A | RNA (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- CADPS2 | c.-8C>G | 5'UTR (SNP) | VAF 10/59 reads (17%) | catalogued as rs988297020; called by muse, mutect2, varscan2
- CCDC7 | c.1802-10463G>T | Intron (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- CNKSR1 | chr1:26177504 A>T | 5'Flank (SNP) | VAF 14/103 reads (14%) | called by muse, varscan2
- COL28A1 | c.1998+869G>T | Intron (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- CPS1 | c.3667-39G>A | Intron (SNP) | VAF 23/166 reads (14%) | called by muse, mutect2, varscan2
- CRISPLD1 | c.*24A>G | 3'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- DENND4C | c.5676-57G>T | Intron (SNP) | VAF 52/106 reads (49%) | called by muse, mutect2, varscan2
- ELFN1 | c.-456+5575G>T | Intron (SNP) | VAF 10/23 reads (43%) | called by mutect2, varscan2
- ELMOD1 | c.-86+490G>A | Intron (SNP) | VAF 6/49 reads (12%) | catalogued as rs768902387; called by mutect2, varscan2
- EMBP1 | n.1086A>G | RNA (SNP) | VAF 11/143 reads (8%) | called by muse, mutect2
- ETNK2 | c.519-795G>A | Intron (SNP) | VAF 16/39 reads (41%) | called by muse, varscan2
- FEZ1 | c.939+42C>T | Intron (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- GCNT2 | chr6:10633955 G>A | 3'Flank (SNP) | VAF 22/106 reads (21%) | catalogued as rs375099541; called by muse, mutect2, varscan2
- GPATCH2L | c.984+52G>T | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-2274G>A | Intron (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- GYG2P1 | n.432T>A | RNA (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102079G>T | Intron (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1167A>T | RNA (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- HTR3A | c.*521G>T | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- ITGB7 | c.574+97G>T | Intron (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- KAZALD1 | chr10:101067988 C>T | 3'Flank (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- KCNAB2 | c.804+469A>C | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- LINC00452 | n.980C>A | RNA (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- LINC01036 | n.131G>T | RNA (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- LINC02876 | n.156T>A | RNA (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- LINGO3 | c.-117G>T | 5'UTR (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- LRRC7 | c.*25A>T | 3'UTR (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- LY75 | c.*2T>A | 3'UTR (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- MICALL2 | c.*23G>T | 3'UTR (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- MIR187 | n.52C>A | RNA (SNP) | VAF 7/65 reads (11%) | catalogued as rs750883328; called by muse, mutect2, varscan2
- MORF4 | n.726G>T | RNA (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- MORF4 | n.725T>G | RNA (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- NBPF22P | n.458C>A | RNA (SNP) | VAF 39/317 reads (12%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2299G>T | Intron (SNP) | VAF 24/213 reads (11%) | catalogued as rs746731617; called by muse, mutect2, varscan2
- OR52B1P | n.600G>C | RNA (SNP) | VAF 11/57 reads (19%) | catalogued as rs1436298446; called by muse, mutect2, varscan2
- PDXDC1 | chr16:14974939 C>A | 5'Flank (SNP) | VAF 19/151 reads (13%) | catalogued as rs1323639929; called by muse, mutect2, varscan2
- PEG3 | c.-187C>A | 5'UTR (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- PHF14 | c.*41G>C | 3'UTR (SNP) | VAF 42/237 reads (18%) | called by muse, mutect2, varscan2
- PRRX1 | c.599+3824C>T | Intron (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- RASGEF1A | c.*17G>T | 3'UTR (SNP) | VAF 5/21 reads (24%) | called by mutect2, varscan2
- RPL37AP1 | chr20:44461935 G>A | 3'Flank (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- TMEM135 | c.*5493G>A | 3'UTR (SNP) | VAF 21/129 reads (16%) | called by muse, mutect2, varscan2
- TMEM68 | c.494-373G>T | Intron (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- TTR | c.336+10C>A | Intron (SNP) | VAF 65/476 reads (14%) | called by muse, mutect2, varscan2
- VN1R10P | n.684C>A | RNA (SNP) | VAF 27/131 reads (21%) | called by muse, mutect2, varscan2
- XKR4 | c.806+61091C>A | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2, varscan2
- ZNF300P1 | n.1199C>T | RNA (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- ZNF483 | c.*6633T>A | 3'UTR (SNP) | VAF 32/175 reads (18%) | called by muse, mutect2, varscan2
- ZNF575 | chr19:43531857 C>T | 5'Flank (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- ZNF677 | c.169+13G>C | Intron (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- ZNF727 | c.-31G>C | 5'UTR (SNP) | VAF 55/206 reads (27%) | called by muse, mutect2, varscan2
- ZNF971P | n.928G>A | RNA (SNP) | VAF 50/232 reads (22%) | called by muse, mutect2, varscan2
